Surgical pathology report (de-identified scan), TCGA case TCGA-06-0645, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0645-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

7A-06-0645

CLINICAL HISTORY

The patient is a [REDACTED] who presents emergently with an intracranial mass lesion.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, excision biopsy
B: Brain, left frontal brain tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. B. Brain, left frontal tumor, biopsy: glioblastoma (WHO grade IV) (see comment).

COMMENT

The results of MGMT promoter methylation analysis will be reported in an addendum.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE - Methylated MGMT promoter is detected.

Results-Comments

Testing was done on block

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

[page 2 of 3]
provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

INTRA-OPERATIVE CONSULTATION

A. Brain, mass lesion, excisional biopsy: glioblastoma.

GROSS DESCRIPTION

A. Received from the operating room are irregular fragments of tan tissue measuring approximately 0.5 x 0.4 x 0.3 cm in aggregate. Small portions are used for intraoperative smears and frozen sections. The residual frozen tissue is submitted in A1 and the unfrozen tissue is submitted in A2.

B.

Left frontal brain tumor.

None.

Received are two irregular tan-brown fragments of slightly bosselated tissue, 1.0 and 1.3 cm. in greatest dimensions. Cut surface is tan-brown and homogeneous.

B1 smaller tissue fragment; B2 larger tissue fragment.

MICROSCOPIC DESCRIPTION

Permanent sections of specimens A and B show a pleomorphic high-grade astrocytic neoplasm demonstrating frequent mitotic figures and extensive microvascular proliferation. Immunostains performed on block A2 demonstrate that the tumor is GFAP and p53 immunoreactive.

ICD-9(s):
239.6 239.6

Histo Data

Part A: Brain, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
mGFAP-DA x 1	2		
H/E x 1	2		
Lev 2 H/E x 1	2		
P53DO7 x 1	2		

Part B: Brain, left frontal brain tumor, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
H/E x 1	2		

[page 3 of 3]
MGMT x 1

2

*** End of Report ***

Source: NCI Genomic Data Commons file 5dc9128a-90b8-412f-bc3e-25de9c215f8a (TCGA-06-0645.B006FA12-7893-48F9-81F1-93B28989FFE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).